Somatic mutation profile of tumor specimen TARGET-10-PAREKH-09A (aliquot TARGET-10-PAREKH-09A-01D) from TARGET case TARGET-10-PAREKH, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.3 years (1,930 days).
Specimen TARGET-10-PAREKH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c78462f-f5d3-4307-ab7a-b17a60d5c824.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAREKH-10A (Blood Derived Normal), aliquot TARGET-10-PAREKH-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b534ee09-48d4-4afd-b481-2d2f6ee41e6a

The open-access MAF lists 24 somatic variants for this specimen: 19 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 2, Intron 2, Splice Region 1, 3'Flank 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 6/30 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CCDC168 | c.15170G>T p.R5057I | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV59419424, COSV59423408; called by muse, mutect2, varscan2
- FLRT2 | c.1598C>T p.T533M | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as rs538772019, COSV58136450; called by muse, mutect2, varscan2
- GEM | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs777960854, COSV52598899; called by muse, mutect2, varscan2
- GPR68 | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.94); PolyPhen benign (0.058); catalogued as rs954107593, COSV53176303; called by muse, mutect2, varscan2
- IQCB1 | c.1466G>A p.R489Q | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs778777318, COSV60438126; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KRT34 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs145049293; called by muse, mutect2, varscan2
- NCAM2 | c.1277C>T p.S426L | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV53111396; called by muse, mutect2, varscan2
- NHS | c.2161C>T p.R721C | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs1200104488; called by muse, mutect2, varscan2
- PAPSS1 | c.1261C>T p.R421C | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779975662, COSV99492508; called by muse, mutect2, varscan2
- PREX2 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs201372935, COSV99906079; called by muse, mutect2, varscan2
- UNC13C | c.5590G>A p.E1864K | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated, low confidence (0.39); PolyPhen probably damaging (0.981); catalogued as rs753934007, COSV52858100, COSV99523852; called by muse, mutect2, varscan2
- UNC79 | c.4478del p.K1493Sfs*12 (on ENST00000393151 / NM_001346218.2; = p.K1316Sfs*12 on NM_020818.5) | Frame Shift Del (DEL) | VAF 30/94 reads (32%) | catalogued as rs760213136; called by mutect2, varscan2
- CHAF1A | c.2004_2005insA p.D669Rfs*6 | Frame Shift Ins (INS) | VAF 6/37 reads (16%) | called by mutect2, pindel, varscan2
- CLASRP | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- CSDE1 | c.754A>G p.T252A (on ENST00000358528 / NM_001007553.3; = p.T221A on NM_007158.6) | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- DOP1B | c.1692A>C p.K564N | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC9 | c.1460T>C p.L487P | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- SMG5 | c.909C>T p.S303= | Splice Region (SNP) | VAF 2/8 reads (25%) | called by muse, mutect2
- AKAP6 | c.5151G>A p.S1717= | Silent (SNP) | VAF 18/120 reads (15%) | catalogued as rs1398288716, COSV55208465, COSV55231445; called by muse, mutect2, varscan2
- HHIP | c.1890G>A p.E630= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs1251240370; called by muse, mutect2, varscan2
- GAS7 | c.184-45G>A | Intron (SNP) | VAF 31/83 reads (37%) | called by muse, mutect2, varscan2
- RNU6-452P | chr10:27334201 C>A | 3'Flank (SNP) | VAF 22/67 reads (33%) | called by muse, mutect2, varscan2
- SLC12A9 | c.1343+15_1343+16insAAGG | Intron (INS) | VAF 35/85 reads (41%) | called by mutect2, pindel, varscan2
